Somatic mutation profile of tumor specimen HCM-SANG-0307-C15-01B (aliquot HCM-SANG-0307-C15-01B-01D-A79M-36) from HCMI case HCM-SANG-0307-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0307-C15-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fbe0888-f5f8-418f-8064-ef3c7892466b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0307-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0307-C15-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88a1521e-cb53-409c-b955-7b8dba51ac80

The open-access MAF lists 195 somatic variants for this specimen: 146 protein-altering or splice-affecting, 44 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 44, Nonsense Mutation 7, Frame Shift Ins 3, In Frame Del 3, Intron 3, Frame Shift Del 1, 3'UTR 1, Splice Region 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PROM1 | c.730C>T p.R244* | Nonsense Mutation (SNP) | VAF 54/194 reads (28%) | catalogued as rs373331232, CM141757; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.788A>C p.K263T | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs1470277337, COSV51421462, COSV99271411; called by muse, mutect2, varscan2
- ARFGEF2 | c.2251G>A p.A751T | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV64211831, COSV64212304; called by muse, mutect2
- ATP2B3 | c.3436G>A p.E1146K | Missense Mutation (SNP) | VAF 167/333 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as rs1364282837, COSV99051136; called by muse, mutect2, varscan2
- C1QL2 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 99/645 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.057); catalogued as COSV55607270; called by muse, mutect2, varscan2
- CACNG2 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 163/574 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55632156; called by muse, mutect2, varscan2
- CACNG5 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 130/327 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1333562967, COSV50055154; called by muse, mutect2, varscan2
- CDH26 | c.1793C>G p.A598G | Missense Mutation (SNP) | VAF 109/405 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as rs370792557, COSV99722728; called by muse, mutect2, varscan2
- CHRNA2 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 118/442 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1370103246; called by muse, mutect2, varscan2
- CNTNAP5 | c.1253T>C p.L418P | Missense Mutation (SNP) | VAF 34/366 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1275957608; called by muse, mutect2
- DBH | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 118/438 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1348610910, COSV55040968; called by muse, mutect2, varscan2
- EPB42 | c.1636G>A p.G546S (on ENST00000441366 / NM_001114134.2; = p.G576S on NM_000119.3) | Missense Mutation (SNP) | VAF 113/253 reads (45%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs369068948; ClinVar: uncertain significance; called by muse, varscan2
- EPHA6 | c.1391A>C p.K464T | Missense Mutation (SNP) | VAF 56/346 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV67572128; called by muse, mutect2, varscan2
- FGF6 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746672335, COSV57403329; called by mutect2, varscan2
- GRM1 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 10/319 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV51138888; called by muse, mutect2
- HCFC1 | c.4563G>T p.Q1521H | Missense Mutation (SNP) | VAF 23/400 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.694); catalogued as rs1557113061; called by muse, mutect2
- HMCN1 | c.3080A>C p.K1027T | Missense Mutation (SNP) | VAF 29/359 reads (8%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.505); catalogued as COSV54889062, COSV99623133, COSV99637782; called by muse, mutect2
- IFNAR1 | c.1111A>G p.I371V | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.08); catalogued as rs199515722; called by muse, mutect2, varscan2
- IGSF1 | c.3523T>G p.L1175V | Missense Mutation (SNP) | VAF 144/260 reads (55%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as COSV100812491; called by muse, mutect2, varscan2
- INHBA | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 30/528 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV54219500, COSV54222254; called by muse, mutect2
- IRS1 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 105/528 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs771146954; called by muse, mutect2
- IRX6 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 162/531 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs200259402, COSV51862362; called by muse, mutect2, varscan2
- KCNQ5 | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 106/524 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as rs1013371738; called by muse, varscan2
- KCNT2 | c.3381A>T p.Q1127H | Missense Mutation (SNP) | VAF 76/298 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.192); catalogued as COSV99657642; called by muse, mutect2, varscan2
- KIF4B | c.2424A>C p.Q808H | Missense Mutation (SNP) | VAF 56/319 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV70529115; called by muse, mutect2, varscan2
- KLHL4 | c.1543G>A p.G515S | Missense Mutation (SNP) | VAF 62/111 reads (56%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); catalogued as rs1463129923; called by muse, mutect2, varscan2
- KMT2C | c.13597C>T p.R4533* | Nonsense Mutation (SNP) | VAF 88/337 reads (26%) | catalogued as COSV51471125; called by muse, mutect2, varscan2
- LAMA1 | c.2276C>T p.A759V | Missense Mutation (SNP) | VAF 101/356 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs759093705; called by muse, mutect2, varscan2
- LAPTM4B | c.562C>T p.R188C (on ENST00000445593; = p.R97C on NM_018407.6) | Missense Mutation (SNP) | VAF 80/337 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1004267738; called by muse, mutect2, varscan2
- LINGO3 | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 32/602 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.041); catalogued as rs746504285; called by muse, mutect2
- LRP1B | c.9838A>C p.N3280H | Missense Mutation (SNP) | VAF 59/306 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV67224089; called by muse, mutect2, varscan2
- MAP3K12 | c.1646A>G p.K549R | Missense Mutation (SNP) | VAF 71/347 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV99913566; called by muse, mutect2, varscan2
- MDGA1 | c.1270G>A p.V424M | Missense Mutation (SNP) | VAF 72/267 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs774142739, COSV51801335; called by muse, mutect2, varscan2
- MTMR8 | c.164T>A p.I55N | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66395262; called by muse, mutect2
- NLRC3 | c.2212G>A p.G738S | Missense Mutation (SNP) | VAF 56/328 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57089501; called by muse, mutect2, varscan2
- OGFOD3 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 87/383 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as rs368244831; called by muse, mutect2, varscan2
- OR10D3 | c.83T>G p.F28C | Missense Mutation (SNP) | VAF 42/392 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as COSV100591159; called by muse, mutect2, varscan2
- OR13C5 | c.84dup p.V29Cfs*93 | Frame Shift Ins (INS) | VAF 60/350 reads (17%) | catalogued as rs1234786996; called by mutect2, pindel, varscan2
- OR4S2 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 24/448 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs142336485; called by muse, mutect2
- OR51E1 | c.43T>G p.F15V | Missense Mutation (SNP) | VAF 95/342 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67809382; called by muse, mutect2
- OR51E1 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 53/399 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1431298367, COSV67810461, COSV67810970; called by muse, mutect2, varscan2
- OXTR | c.1079C>T p.T360M | Missense Mutation (SNP) | VAF 70/426 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs199856198; called by muse, mutect2, varscan2
- PAXBP1 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 112/301 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV99269307; called by muse, mutect2, varscan2
- PKD1 | c.7091C>T p.P2364L | Missense Mutation (SNP) | VAF 46/301 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs573561064; called by muse, mutect2, varscan2
- POC1B | c.940C>T p.L314F | Missense Mutation (SNP) | VAF 21/328 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV100544510; called by muse, mutect2
- POM121L12 | c.335T>C p.L112P | Missense Mutation (SNP) | VAF 31/694 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.542); catalogued as COSV68692948; called by muse, mutect2
- POTEC | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 154/579 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs878887288, COSV62802455; called by muse, mutect2, varscan2
- PRKAG3 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 40/294 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.63); catalogued as rs750886488; called by muse, mutect2, varscan2
- PTK7 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 134/470 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as rs747399017, COSV104369389; called by muse, mutect2, varscan2
- PTPRT | c.1982T>G p.L661R | Missense Mutation (SNP) | VAF 62/409 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100625481; called by muse, mutect2, varscan2
- SCN11A | c.3151C>G p.Q1051E | Missense Mutation (SNP) | VAF 50/404 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV56570252; called by muse, mutect2, varscan2
- SH3BP2 | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 34/287 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs376871555, COSV62554484; called by muse, mutect2, varscan2
- SHANK1 | c.2223G>A p.M741I | Missense Mutation (SNP) | VAF 125/389 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as rs1275116300, COSV99521518; called by muse, mutect2, varscan2
- SLC5A2 | c.962A>G p.K321R | Missense Mutation (SNP) | VAF 54/387 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201511529, CM050098; called by muse, mutect2, varscan2
- SLC7A4 | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 144/356 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.288); catalogued as rs138722356; called by muse, mutect2, varscan2
- SOX5 | c.913A>G p.S305G | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.206); catalogued as COSV58628690; called by muse, mutect2, varscan2
- SYT4 | c.607_609del p.K203del | In Frame Del (DEL) | VAF 88/244 reads (36%) | catalogued as rs1358051088; called by pindel, varscan2
- TECTA | c.2452G>C p.E818Q | Missense Mutation (SNP) | VAF 114/390 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.684); catalogued as COSV99879478; called by muse, mutect2, varscan2
- TNK2 | c.1522dup p.Q508Pfs*12 | Frame Shift Ins (INS) | VAF 57/176 reads (32%) | catalogued as rs754147115; called by mutect2, varscan2
- TPTE | c.1268C>T p.S423L (on ENST00000618007 / NM_199261.4; = p.S405L on NM_199259.4) | Missense Mutation (SNP) | VAF 21/301 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as rs570468666; called by muse, mutect2
- TUSC3 | c.231A>G p.I77M | Missense Mutation (SNP) | VAF 28/491 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs1452732235; called by muse, mutect2
- TWIST1 | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 94/422 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.04); catalogued as rs1444006714; called by muse, varscan2
- ULK3 | c.999+1G>A p.X333_splice | Splice Site (SNP) | VAF 60/237 reads (25%) | catalogued as rs903676053; called by muse, mutect2, varscan2
- ZNF804B | c.824T>G p.L275R | Missense Mutation (SNP) | VAF 47/285 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV60857444; called by muse, mutect2, varscan2
- ADGRD1 | c.2267A>G p.K756R | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.414); called by muse, mutect2
- AFF2 | c.2245A>C p.I749L | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2
- AP1B1 | c.2458A>T p.I820F | Missense Mutation (SNP) | VAF 85/344 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- CCDC168 | c.11809G>T p.A3937S | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.07); called by muse, mutect2
- CEP295 | c.2930A>G p.H977R | Missense Mutation (SNP) | VAF 43/313 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CERS6 | c.83_103del p.E28_Q34del | In Frame Del (DEL) | VAF 91/347 reads (26%) | called by mutect2, pindel, varscan2
- CHL1 | c.3124G>C p.E1042Q (on ENST00000397491 / NM_001253387.1; = p.E1058Q on NM_006614.4) | Missense Mutation (SNP) | VAF 85/418 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CKAP2 | c.238G>C p.D80H (on ENST00000378037 / NM_001098525.2; = p.D79H on NM_018204.5) | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- CLMP | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 52/466 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL24A1 | c.1966T>G p.F656V | Missense Mutation (SNP) | VAF 12/247 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); called by muse, mutect2
- COL9A3 | c.811G>T p.G271C | Missense Mutation (SNP) | VAF 43/454 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- CPN2 | c.77G>A p.C26Y | Missense Mutation (SNP) | VAF 56/333 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- CRB1 | c.3194C>A p.T1065K | Missense Mutation (SNP) | VAF 68/307 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- DCLK1 | c.73T>C p.S25P | Missense Mutation (SNP) | VAF 123/490 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DDX47 | c.529G>C p.D177H | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DLGAP2 | c.3082C>T p.R1028* | Nonsense Mutation (SNP) | VAF 217/681 reads (32%) | called by muse, mutect2, varscan2
- DNAH11 | c.8234T>G p.V2745G | Missense Mutation (SNP) | VAF 62/264 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- DPYS | c.1282T>G p.F428V | Missense Mutation (SNP) | VAF 41/308 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EDC4 | c.4079C>T p.S1360F | Missense Mutation (SNP) | VAF 135/408 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- ELF3 | c.867C>G p.N289K | Missense Mutation (SNP) | VAF 81/377 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ELMO1 | c.1484A>C p.K495T | Missense Mutation (SNP) | VAF 50/368 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- FAM135B | c.3319A>T p.K1107* | Nonsense Mutation (SNP) | VAF 55/213 reads (26%) | called by muse, mutect2, varscan2
- FBXL16 | c.688G>C p.D230H | Missense Mutation (SNP) | VAF 136/463 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- FCRL5 | c.1379A>C p.K460T | Missense Mutation (SNP) | VAF 37/291 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- FREM3 | c.4092A>C p.E1364D | Missense Mutation (SNP) | VAF 38/263 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GARRE1 | c.934A>C p.S312R | Missense Mutation (SNP) | VAF 29/334 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- GLI3 | c.1093A>C p.S365R | Missense Mutation (SNP) | VAF 79/398 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- HMCN1 | c.12555A>C p.Q4185H | Missense Mutation (SNP) | VAF 51/270 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- HPR | c.226A>T p.I76L | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HTR3A | c.925T>C p.F309L | Missense Mutation (SNP) | VAF 45/390 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- IGKV3D-7 | c.31T>G p.F11V | Missense Mutation (SNP) | VAF 64/487 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IRAK1 | c.1340T>G p.V447G | Missense Mutation (SNP) | VAF 162/292 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ITGAD | c.1561G>C p.G521R | Missense Mutation (SNP) | VAF 51/369 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGB6 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 27/259 reads (10%) | called by muse, mutect2, varscan2
- KCNA7 | c.838A>C p.I280L | Missense Mutation (SNP) | VAF 75/351 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- LRP1B | c.13423dup p.T4475Nfs*3 | Frame Shift Ins (INS) | VAF 42/129 reads (33%) | called by mutect2, pindel, varscan2
- LRP1B | c.1236A>C p.Q412H | Missense Mutation (SNP) | VAF 79/175 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRP5 | c.2765G>A p.G922D | Missense Mutation (SNP) | VAF 109/655 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MSN | c.782A>T p.D261V | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, mutect2
- NGF | c.340A>T p.N114Y | Missense Mutation (SNP) | VAF 39/305 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NR5A2 | c.605C>T p.A202V (on ENST00000367362 / NM_205860.3; = p.A156V on NM_003822.5) | Missense Mutation (SNP) | VAF 65/599 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- NUFIP1 | c.1463A>T p.N488I | Missense Mutation (SNP) | VAF 12/341 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2
- OLFM1 | c.589G>C p.E197Q (on ENST00000371793 / NM_001282611.2; = p.E179Q on NM_014279.5) | Missense Mutation (SNP) | VAF 18/454 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2
- OR14C36 | c.793G>T p.A265S | Missense Mutation (SNP) | VAF 16/313 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.034); called by muse, mutect2
- OR2T1 | c.671T>G p.V224G | Missense Mutation (SNP) | VAF 108/450 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR51B6 | c.250T>C p.W84R | Missense Mutation (SNP) | VAF 97/381 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- OR7G2 | c.343T>C p.Y115H | Missense Mutation (SNP) | VAF 61/292 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- OR8D1 | c.757G>T p.G253W | Missense Mutation (SNP) | VAF 70/295 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA9 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 24/638 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); called by muse, mutect2
- PPP1R3A | c.366A>C p.Q122H | Missense Mutation (SNP) | VAF 43/290 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PRRT1B | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 22/773 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- RAPH1 | c.3242_3243del p.E1081Afs*7 | Frame Shift Del (DEL) | VAF 36/304 reads (12%) | called by pindel, varscan2
- RBL1 | c.3078G>C p.Q1026H | Missense Mutation (SNP) | VAF 78/389 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RFC1 | c.502T>C p.Y168H | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- RIBC2 | c.157G>C p.V53L | Missense Mutation (SNP) | VAF 30/263 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ROS1 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 58/239 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- RYR2 | c.5136C>A p.S1712R | Missense Mutation (SNP) | VAF 109/397 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SCART1 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 176/483 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SCN10A | c.5132T>A p.L1711H | Missense Mutation (SNP) | VAF 32/369 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SHOX2 | c.483G>C p.E161D (on ENST00000441443 / NM_006884.3; = p.E185D on NM_003030.4) | Missense Mutation (SNP) | VAF 68/469 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- SIPA1L1 | c.965T>A p.V322D | Missense Mutation (SNP) | VAF 116/257 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SLCO1B1 | c.349T>G p.F117V | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- SLCO4C1 | c.1810A>C p.R604= | Splice Region (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- SPRED3 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 35/418 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- STXBP5L | c.1658T>C p.V553A | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCN1 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 53/159 reads (33%) | called by muse, mutect2, varscan2
- TLR3 | c.5G>C p.R2T | Missense Mutation (SNP) | VAF 73/249 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TNRC6B | c.4825A>C p.K1609Q (on ENST00000454349 / NM_001162501.2; = p.K1499Q on NM_015088.3) | Missense Mutation (SNP) | VAF 130/488 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TP53 | c.858_881del p.E287_E294del | In Frame Del (DEL) | VAF 122/336 reads (36%) | called by mutect2, pindel, varscan2
- TRAV5 | c.325T>G p.F109V | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- TRAV8-4 | c.264G>C p.K88N | Missense Mutation (SNP) | VAF 94/302 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- TRPA1 | c.1970A>C p.E657A | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- TRPA1 | c.530A>G p.N177S | Missense Mutation (SNP) | VAF 71/214 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRPA1 | c.107T>G p.L36R | Missense Mutation (SNP) | VAF 22/345 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.202); called by muse, mutect2
- TRPM6 | c.736T>C p.S246P | Missense Mutation (SNP) | VAF 110/444 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- TSHZ3 | c.1742A>G p.E581G | Missense Mutation (SNP) | VAF 14/366 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- VCX3A | c.257A>G p.Q86R | Missense Mutation (SNP) | VAF 34/474 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2
- WDR17 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF208 | c.2928A>C p.E976D | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ZNF445 | c.2584C>G p.H862D | Missense Mutation (SNP) | VAF 74/286 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF540 | c.1954C>T p.Q652* | Nonsense Mutation (SNP) | VAF 11/151 reads (7%) | called by muse, mutect2
- ZNF746 | c.1349G>A p.G450D | Missense Mutation (SNP) | VAF 62/495 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by mutect2, varscan2
- AMER2 | c.285G>A p.S95= | Silent (SNP) | VAF 226/495 reads (46%) | catalogued as rs1225730657, COSV100766190; called by muse, mutect2, varscan2
- ANKRD55 | c.942C>A p.V314= | Silent (SNP) | VAF 65/202 reads (32%) | called by muse, mutect2, varscan2
- BAAT | c.870G>A p.L290= | Silent (SNP) | VAF 27/664 reads (4%) | called by muse, mutect2
- COL6A3 | c.5766C>T p.P1922= | Silent (SNP) | VAF 64/469 reads (14%) | called by muse, mutect2, varscan2
- CRB2 | c.3228C>T p.D1076= | Silent (SNP) | VAF 85/726 reads (12%) | catalogued as rs1056136525, COSV63502424; called by muse, mutect2, varscan2
- CT55 | c.168G>T p.S56= | Silent (SNP) | VAF 21/251 reads (8%) | catalogued as COSV52278464; called by muse, mutect2
- DACT3 | c.1122C>T p.A374= | Silent (SNP) | VAF 24/596 reads (4%) | called by muse, mutect2
- DFFB | c.198C>T p.N66= | Silent (SNP) | VAF 40/382 reads (10%) | catalogued as rs1399478611, COSV58214997; called by muse, mutect2, varscan2
- DYSF | c.415C>T p.L139= | Silent (SNP) | VAF 118/331 reads (36%) | called by muse, mutect2, varscan2
- E2F7 | c.1488T>C p.P496= | Silent (SNP) | VAF 43/269 reads (16%) | called by muse, mutect2, varscan2
- FRK | c.610C>T p.L204= | Silent (SNP) | VAF 70/288 reads (24%) | called by muse, mutect2, varscan2
- GABRQ | c.1308T>G p.T436= | Silent (SNP) | VAF 153/323 reads (47%) | called by muse, mutect2, varscan2
- GFRAL | c.37T>C p.L13= | Silent (SNP) | VAF 8/223 reads (4%) | called by muse, mutect2
- IRS1 | c.2880C>G p.V960= | Silent (SNP) | VAF 63/440 reads (14%) | catalogued as rs141976450; called by muse, mutect2, varscan2
- KCNT2 | c.2379T>G p.T793= | Silent (SNP) | VAF 72/285 reads (25%) | called by muse, mutect2, varscan2
- MAGEC1 | c.2448C>T p.S816= | Silent (SNP) | VAF 162/324 reads (50%) | catalogued as COSV53571125; called by muse, mutect2, varscan2
- MCF2 | c.70T>C p.L24= | Silent (SNP) | VAF 10/202 reads (5%) | catalogued as COSV58476896, COSV58478333; called by muse, mutect2
- NKRF | c.1566G>A p.L522= | Silent (SNP) | VAF 157/298 reads (53%) | catalogued as COSV58660741; called by muse, mutect2, varscan2
- NKX2-3 | c.21C>A p.V7= | Silent (SNP) | VAF 49/231 reads (21%) | called by muse, mutect2, varscan2
- NR5A2 | c.624C>T p.T208= (on ENST00000367362 / NM_205860.3; = p.T162= on NM_003822.5) | Silent (SNP) | VAF 80/648 reads (12%) | catalogued as COSV52656504; called by muse, mutect2
- NUDCD3 | c.807C>A p.G269= | Silent (SNP) | VAF 83/313 reads (27%) | catalogued as rs147734736; called by muse, mutect2, varscan2
- OR14A16 | c.312T>G p.S104= | Silent (SNP) | VAF 33/273 reads (12%) | catalogued as COSV62926276; called by muse, mutect2, varscan2
- OR4A15 | c.645C>A p.S215= | Silent (SNP) | VAF 89/397 reads (22%) | called by muse, mutect2, varscan2
- OR4A16 | c.279A>G p.S93= | Silent (SNP) | VAF 124/444 reads (28%) | catalogued as COSV59041716, COSV59044180; called by muse, mutect2, varscan2
- PDGFD | c.396A>G p.G132= | Silent (SNP) | VAF 48/350 reads (14%) | called by muse, mutect2, varscan2
- PPFIBP1 | c.798G>A p.L266= (on ENST00000318304 / NM_177444.3; = p.L235= on NM_003622.4) | Silent (SNP) | VAF 27/579 reads (5%) | called by muse, mutect2
- PREX2 | c.2349T>A p.A783= | Silent (SNP) | VAF 100/321 reads (31%) | catalogued as COSV55756430, COSV55778503; called by muse, mutect2, varscan2
- PSTPIP2 | c.729C>A p.V243= | Silent (SNP) | VAF 27/200 reads (14%) | called by muse, mutect2, varscan2
- RAMP2 | c.81C>T p.L27= | Silent (SNP) | VAF 47/378 reads (12%) | called by muse, mutect2, varscan2
- RBMXL3 | c.2214C>T p.S738= | Silent (SNP) | VAF 151/307 reads (49%) | catalogued as rs952414411, COSV57747740; called by muse, mutect2, varscan2
- ROBO2 | c.1809C>A p.L603= | Silent (SNP) | VAF 91/383 reads (24%) | called by muse, mutect2, varscan2
- ROM1 | c.897C>A p.V299= | Silent (SNP) | VAF 47/349 reads (13%) | called by muse, mutect2, varscan2
- RPE65 | c.294C>A p.I98= | Silent (SNP) | VAF 46/199 reads (23%) | catalogued as rs367983478, COSV52016133; called by muse, mutect2, varscan2
- SAMD1 | c.108G>A p.L36= | Silent (SNP) | VAF 37/404 reads (9%) | called by muse, mutect2
- SLC16A2 | c.1578G>C p.G526= | Silent (SNP) | VAF 20/318 reads (6%) | called by muse, mutect2
- SPOCK1 | c.669A>G p.R223= | Silent (SNP) | VAF 12/344 reads (3%) | called by muse, mutect2
- ST3GAL3 | c.405C>T p.I135= (on ENST00000361392 / NM_174964.4; = p.I120= on NM_006279.5) | Silent (SNP) | VAF 25/233 reads (11%) | called by muse, mutect2, varscan2
- SYT10 | c.342A>G p.K114= | Silent (SNP) | VAF 17/510 reads (3%) | catalogued as COSV57338918; called by muse, mutect2
- TACC2 | c.2976G>A p.K992= | Silent (SNP) | VAF 38/325 reads (12%) | called by muse, mutect2, varscan2
- TNRC6B | c.2274C>T p.N758= | Silent (SNP) | VAF 110/415 reads (27%) | called by muse, mutect2, varscan2
- TRAPPC12 | c.1977C>T p.N659= | Silent (SNP) | VAF 40/212 reads (19%) | catalogued as rs561539161, COSV60850740; called by muse, mutect2, varscan2
- TRHDE | c.261C>T p.G87= | Silent (SNP) | VAF 193/520 reads (37%) | catalogued as rs768763758; called by muse, mutect2, varscan2
- UNC80 | c.3126C>A p.T1042= | Silent (SNP) | VAF 73/437 reads (17%) | called by muse, mutect2, varscan2
- ZNF835 | c.591C>G p.A197= | Silent (SNP) | VAF 65/388 reads (17%) | called by muse, mutect2, varscan2
- ARHGAP28 | c.2030+1892A>G | Intron (SNP) | VAF 39/296 reads (13%) | called by mutect2, varscan2
- CPLANE1 | c.*5132C>G | 3'UTR (SNP) | VAF 25/243 reads (10%) | catalogued as COSV57058051; called by muse, mutect2, varscan2
- DNAAF3 | c.86-40C>T | Intron (SNP) | VAF 110/304 reads (36%) | called by muse, mutect2, varscan2
- PRR12 | c.51+463C>T | Intron (SNP) | VAF 156/432 reads (36%) | catalogued as rs1220433289, COSV69817826; called by muse, mutect2, varscan2
- RAB15 | c.-19G>C | 5'UTR (SNP) | VAF 74/482 reads (15%) | called by muse, mutect2, varscan2
